Somatic mutation profile of tumor specimen TARGET-10-PAPZTS-09A (aliquot TARGET-10-PAPZTS-09A-01D) from TARGET case TARGET-10-PAPZTS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,190 days).
Specimen TARGET-10-PAPZTS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 787336da-9687-4c88-ad79-9f6c8bae006c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZTS-14A (Bone Marrow Normal), aliquot TARGET-10-PAPZTS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a076612-3b73-42e7-a0f7-aa97d6e173e7

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs562863484, COSV61658252; called by muse, mutect2, varscan2
- HCFC1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 169/181 reads (93%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV60077586; called by muse, mutect2, varscan2
- OR8I2 | c.532del p.C178Vfs*7 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | catalogued as rs112181516, COSV56167552; called by mutect2, varscan2
- SPAG17 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762885045, COSV60456915; called by muse, mutect2, varscan2
- ZNF608 | c.2542G>C p.D848H | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV60440204; called by muse, mutect2
- ELF1 | c.1766dup p.Q590Tfs*53 | Frame Shift Ins (INS) | VAF 48/211 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1-69D | chr14:106762091 GTCTCT>CC | Missense Mutation (DEL) | VAF 43/50 reads (86%) | called by pindel, varscan2*
- KCNT2 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLTP | c.1383T>G p.D461E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMC5 | c.659T>G p.F220C | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- HAUS5 | c.1242G>A p.L414= | Silent (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- IBTK | c.3249A>G p.S1083= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- PXDNL | c.2958C>T p.S986= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs952661664, COSV62477568; called by muse, mutect2
- SCAI | c.75A>G p.K25= | Silent (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
